Somatic mutation profile of tumor specimen ALCH-B2LW-TTP1-A (aliquot ALCH-B2LW-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2LW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.8 years (27,674 days).
Specimen ALCH-B2LW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3062f1c9-6006-4702-9b40-81946aba05a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LW-NB1-A (Blood Derived Normal), aliquot ALCH-B2LW-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5714bd5-463d-4177-aaa4-5c3fbbc0ede9

The open-access MAF lists 892 somatic variants for this specimen: 606 protein-altering or splice-affecting, 167 silent, 119 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 524, Silent 167, Intron 60, Nonsense Mutation 56, 5'UTR 20, RNA 16, 3'UTR 13, Splice Region 9, 5'Flank 8, Splice Site 5, Frame Shift Del 4, Frame Shift Ins 4.

Variants (750 of 892; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.6287G>T p.G2096V (on ENST00000614293; = p.G2066V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs867595522; called by muse, mutect2, varscan2
- ABRA | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 86/450 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs371240527; called by mutect2, varscan2
- AC004922.1 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 82/506 reads (16%) | catalogued as rs764935367; called by muse, mutect2, varscan2
- ADAD1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 65/237 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.268); catalogued as COSV56643740; called by muse, mutect2, varscan2
- ADCY10 | c.1890G>C p.L630F | Missense Mutation (SNP) | VAF 104/542 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100896826; called by mutect2, varscan2
- AFG3L2 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 81/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52316054; called by muse, mutect2, varscan2
- AKAP11 | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV50295200; called by muse, mutect2, varscan2
- AKAP5 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 174/515 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57742161; called by muse, varscan2
- AKAP5 | c.1001G>C p.R334T | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV100277999; called by muse, mutect2, varscan2
- ALG12 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 148/461 reads (32%) | PolyPhen probably damaging (1); catalogued as rs769660550; called by muse, mutect2, varscan2
- ALK | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 98/509 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs770435688, COSV66574371; called by muse, mutect2, varscan2
- AMER1 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs756299099; called by muse, mutect2, varscan2
- ANGPTL6 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs759956325; called by muse, mutect2, varscan2
- ANKRD26 | c.2201C>G p.S734* | Nonsense Mutation (SNP) | VAF 63/224 reads (28%) | catalogued as COSV101063260, COSV65774189; called by muse, mutect2, varscan2
- ANKRD31 | c.3143A>G p.Q1048R | Missense Mutation (SNP) | VAF 124/203 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1003677088; called by muse, mutect2, varscan2
- ARHGAP18 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 50/274 reads (18%) | catalogued as rs745609774, COSV63765017; called by muse, mutect2, varscan2
- ARHGAP32 | c.1450G>A p.D484N (on ENST00000310343 / NM_001378025.1; = p.D135N on NM_014715.4) | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs149594456; called by muse, mutect2, varscan2
- ARHGEF15 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 177/291 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62726799; called by muse, mutect2, varscan2
- ASPM | c.7277G>C p.R2426T | Missense Mutation (SNP) | VAF 195/919 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.932); catalogued as COSV54132656; called by muse, mutect2, varscan2
- ATN1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 69/507 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1555143352, COSV63110225; called by muse, mutect2, varscan2
- ATP10A | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1309665531; called by muse, mutect2, varscan2
- ATP1A1 | c.183+8C>G | Splice Region (SNP) | VAF 180/579 reads (31%) | catalogued as rs763923777; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2289G>A p.M763I | Missense Mutation (SNP) | VAF 128/540 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); catalogued as COSV59477706; called by muse, mutect2, varscan2
- AXL | c.1997A>G p.K666R (on ENST00000301178 / NM_021913.5; = p.K657R on NM_001699.6) | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.801); catalogued as rs779623756; called by muse, mutect2, varscan2
- BAAT | c.672C>G p.V224= | Splice Region (SNP) | VAF 67/277 reads (24%) | catalogued as COSV52288153; called by muse, mutect2, varscan2
- BCHE | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs572660949; called by muse, mutect2, varscan2
- BCOR | c.3512C>A p.P1171H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60715869; called by muse, varscan2
- BUD13 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 86/334 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs931465792, COSV99036337, COSV99496168; called by muse, mutect2, varscan2
- C12orf54 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV100011493; called by muse, mutect2, varscan2
- C1QBP | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV56579009; called by muse, mutect2, varscan2
- C9orf131 | c.2617C>T p.Q873* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as COSV100398096; called by muse, mutect2, varscan2
- CALHM3 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs763005961; called by muse, mutect2, varscan2
- CAMK2B | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | catalogued as COSV99323212; called by muse, mutect2, varscan2
- CBY2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.085); catalogued as COSV60117564; called by muse, mutect2, varscan2
- CCDC116 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.121); catalogued as rs919548153; called by muse, mutect2, varscan2
- CCDC141 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 76/427 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55377357, COSV99836606; called by muse, mutect2, varscan2
- CD101 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs768501974; called by muse, mutect2, varscan2
- CDH12 | c.1810G>T p.E604* | Nonsense Mutation (SNP) | VAF 188/572 reads (33%) | catalogued as COSV66385717; called by muse, mutect2, varscan2
- CDH2 | c.1822C>G p.Q608E | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV99295887; called by muse, mutect2, varscan2
- CDKL5 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 183/640 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.157); catalogued as COSV101184080; called by muse, mutect2, varscan2
- CEL | c.2245C>A p.Q749K (on ENST00000673714; = p.Q746K on NM_001807.6) | Missense Mutation (SNP) | VAF 165/406 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60830154; called by muse, mutect2, varscan2
- CEP170 | c.2774G>A p.R925K | Missense Mutation (SNP) | VAF 73/384 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.323); catalogued as COSV100317152; called by muse, varscan2
- CEP63 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 113/335 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59676394; called by muse, mutect2, varscan2
- CHRAC1 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55270206; called by muse, mutect2, varscan2
- CLCA1 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 86/371 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs757375165; called by muse, mutect2, varscan2
- CLCN1 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 166/423 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CM042006; called by muse, mutect2, varscan2
- CNPY1 | c.39G>T p.K13N | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV58788818; called by muse, mutect2, varscan2
- CNTNAP5 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 140/625 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV70496548; called by muse, mutect2, varscan2
- CPAMD8 | c.1904C>T p.S635L (on ENST00000651564; = p.S588L on NM_015692.5) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV52233037; called by muse, mutect2, varscan2
- CROCC2 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 122/292 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs939804732, COSV101376394; called by muse, mutect2, varscan2
- CRPPA | c.877G>C p.E293Q (on ENST00000407010 / NM_001368197.1; = p.E243Q on NM_001101417.4) | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV101235401; called by muse, mutect2
- CSMD2 | c.9250C>G p.R3084G | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV53877306; called by muse, mutect2
- CTSW | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1018165761, COSV57173524; called by muse, mutect2, varscan2
- CYFIP2 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59033233; called by muse, mutect2, varscan2
- CYP3A5 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56122612; called by muse, mutect2, varscan2
- DCAF8L2 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 113/156 reads (72%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV70548244; called by muse, mutect2, varscan2
- DCDC1 | c.2035T>A p.F679I | Missense Mutation (SNP) | VAF 133/235 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as COSV60857105; called by muse, mutect2, varscan2
- DGKI | c.3071C>G p.T1024R | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.876); catalogued as rs760525641; called by muse, mutect2, varscan2
- DKK3 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 115/360 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs752466547, COSV58868714; called by muse, mutect2, varscan2
- DNAH3 | c.6605G>T p.R2202L | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99770161; called by muse, mutect2, varscan2
- DRC1 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 108/310 reads (35%) | catalogued as COSV56531978; called by muse, mutect2, varscan2
- DUSP19 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1003374103; called by muse, mutect2, varscan2
- DUSP4 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs773776161; called by muse, mutect2, varscan2
- EBF3 | c.889G>A p.G297R (on ENST00000355311 / NM_001375392.1; = p.G288R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62478455; called by muse, varscan2
- ELAPOR2 | c.2610G>C p.E870D (on ENST00000450689 / NM_001142749.3; = p.E703D on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/365 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51887003; called by muse, mutect2, varscan2
- ERF | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.014); catalogued as COSV55897251; called by muse, mutect2, varscan2
- ESPNL | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as rs1220828666; called by muse, mutect2, varscan2
- FAM193A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 169/1372 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs769627283; called by muse, mutect2, varscan2
- FAM83C | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199571076; called by muse, mutect2, varscan2
- FARSA | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as rs1239311203; called by muse, mutect2, varscan2
- FBN1 | c.8224G>T p.E2742* | Nonsense Mutation (SNP) | VAF 81/298 reads (27%) | catalogued as CM077252, COSV57310226; called by muse, mutect2, varscan2
- FBXO27 | c.20G>C p.R7T | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs1361536016; called by muse, mutect2, varscan2
- FKBP15 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | catalogued as COSV53039848; called by muse, mutect2, varscan2
- FLNA | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 79/116 reads (68%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.113); catalogued as rs782292045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FNDC1 | c.5231C>T p.S1744L | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369189702; called by muse, mutect2, varscan2
- FUT1 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 108/411 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV59570091; called by muse, mutect2, varscan2
- GFOD1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as rs370172658; called by muse, mutect2, varscan2
- GLIPR1L2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV66331848; called by muse, mutect2, varscan2
- GPATCH2 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV65127703; called by muse, mutect2, varscan2
- GRM1 | c.173C>G p.P58R | Missense Mutation (SNP) | VAF 108/521 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as rs1455857096, COSV51177288; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1071C>G p.I357M | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56090047; called by muse, mutect2, varscan2
- H3C12 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as COSV58152334, COSV58154015; called by muse, mutect2, varscan2
- HECW1 | c.3532G>C p.E1178Q | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV101224300; called by muse, mutect2, varscan2
- HIP1 | c.2213C>G p.S738C | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV61192039; called by muse, mutect2, varscan2
- HOOK2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53402269; called by muse, mutect2
- HRG | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 91/615 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs138389406; called by muse, mutect2, varscan2
- IFT140 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV101276311; called by muse, mutect2, varscan2
- IKZF1 | c.1206C>A p.S402R | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58781440; called by muse, mutect2, varscan2
- IL5RA | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV56523393; called by muse, mutect2, varscan2
- INPP5A | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs776545394; called by muse, mutect2, varscan2
- INTS1 | c.4669G>C p.E1557Q | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV101247276; called by muse, mutect2
- IZUMO1 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 128/571 reads (22%) | catalogued as COSV55803613; called by muse, mutect2, varscan2
- JUNB | c.221C>G p.S74W | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99041686; called by muse, mutect2, varscan2
- KANK3 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100445153; called by muse, mutect2, varscan2
- KCNQ2 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 152/237 reads (64%) | catalogued as CM1414128, COSV60439743; called by muse, mutect2, varscan2
- KMT2A | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 112/374 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV63283766; called by muse, mutect2, varscan2
- KRT2 | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 264/837 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59012536; called by muse, mutect2, varscan2
- KRTAP5-9 | c.407C>A p.S136* | Nonsense Mutation (SNP) | VAF 168/474 reads (35%) | catalogued as COSV73200268; called by muse, mutect2, varscan2
- LAMA2 | c.639G>A p.E213= | Splice Region (SNP) | VAF 211/410 reads (51%) | catalogued as COSV70342345; called by muse, mutect2, varscan2
- LCE1D | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 320/670 reads (48%) | PolyPhen probably damaging (1); catalogued as rs745909824, COSV58271381; called by muse, varscan2
- LENG8 | c.1737G>C p.L579F | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418113; called by muse, mutect2, varscan2
- LIMS1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1230294736, COSV100185367; called by muse, mutect2, varscan2
- LPA | c.3981T>G p.D1327E | Missense Mutation (SNP) | VAF 290/735 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV60298055; called by muse, mutect2, varscan2
- LRP4 | c.4930G>C p.D1644H | Missense Mutation (SNP) | VAF 148/614 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs192480207; called by muse, mutect2, varscan2
- MADD | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.573); catalogued as COSV60620276; called by muse, mutect2, varscan2
- MAP2 | c.4652G>T p.R1551L | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557375; called by muse, mutect2, varscan2
- MB21D2 | c.94C>G p.R32G | Missense Mutation (SNP) | VAF 79/430 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV66662492; called by muse, mutect2, varscan2
- MMAB | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 118/674 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs138708209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPC1 | c.943C>T p.Q315* (on ENST00000550270 / NM_206820.2; = p.Q340* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 84/506 reads (17%) | catalogued as COSV100637737, COSV100637879; called by muse, mutect2, varscan2
- MYBPC2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs753996160, COSV63097720; called by muse, mutect2, varscan2
- MYBPC2 | c.2662G>T p.V888L | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as rs1016914605; called by muse, mutect2, varscan2
- MYO18A | c.4158G>C p.K1386N | Missense Mutation (SNP) | VAF 148/253 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1052121590; called by muse, mutect2, varscan2
- MYO3B | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759563311; called by muse, mutect2, varscan2
- NAA25 | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 96/507 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1255551852; called by muse, mutect2, varscan2
- NCF2 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 98/517 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs755689355, COSV100838917; called by muse, mutect2, varscan2
- NEXN | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 93/397 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53937451; called by muse, varscan2
- NINL | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as rs781098435; called by muse, mutect2, varscan2
- NLRC4 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 70/363 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749572443; called by muse, mutect2, varscan2
- NOXO1 | c.442G>C p.E148Q (on ENST00000397280 / NM_172168.3; = p.E142Q on NM_144603.4) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs777368177; called by muse, mutect2, varscan2
- NSUN3 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113331; called by muse, mutect2, varscan2
- NUP153 | c.2544C>G p.F848L | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs776659435; called by muse, mutect2, varscan2
- OIT3 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 154/237 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs140044157; called by muse, mutect2, varscan2
- OR2L2 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 198/498 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs754806310; called by muse, mutect2, varscan2
- OR2T34 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 159/653 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs775871954; called by muse, mutect2, varscan2
- OR2W3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.77); catalogued as COSV64457369; called by muse, mutect2
- OR5P3 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV60429384; called by muse, mutect2, varscan2
- P2RX1 | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 334/496 reads (67%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.727); catalogued as COSV56654243; called by muse, mutect2, varscan2
- PCDH15 | c.5553C>G p.N1851K | Missense Mutation (SNP) | VAF 160/860 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV57327965; called by muse, mutect2, varscan2
- PCDH15 | c.3884G>C p.G1295A | Missense Mutation (SNP) | VAF 81/280 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV57309713; called by muse, mutect2, varscan2
- PCDHA10 | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 121/199 reads (61%) | catalogued as COSV100250712; called by muse, mutect2, varscan2
- PCDHA7 | c.1461C>A p.N487K | Missense Mutation (SNP) | VAF 309/473 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65344533; called by muse, mutect2, varscan2
- PCDHAC2 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 72/222 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53850223; called by muse, mutect2, varscan2
- PCDHAC2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs782716187, COSV53842989; called by muse, mutect2, varscan2
- PCDHGA10 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1216701146, COSV99538913; called by muse, mutect2, varscan2
- PCNT | c.4469A>T p.H1490L | Missense Mutation (SNP) | VAF 183/313 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs1370295500; called by muse, mutect2, varscan2
- PDE4DIP | c.6236del p.G2079Vfs*43 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs1553625021; called by mutect2, varscan2
- PEG3 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs769481702; called by muse, mutect2, varscan2
- PKP4 | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV61579852; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.239); catalogued as rs1204230169; called by muse, mutect2, varscan2
- POLE | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761055730; called by muse, mutect2, varscan2
- PPFIA2 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 87/231 reads (38%) | catalogued as COSV61032719, COSV61056451; called by muse, mutect2, varscan2
- PPFIA3 | c.2363C>G p.S788C | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV61954902; called by muse, mutect2, varscan2
- PPFIBP1 | c.1891C>T p.R631* (on ENST00000318304 / NM_177444.3; = p.R625* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 51/260 reads (20%) | catalogued as rs151071761; called by muse, mutect2, varscan2
- PPL | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52169025; called by muse, mutect2, varscan2
- PPP1R3A | c.1110C>G p.F370L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99493745; called by muse, mutect2, varscan2
- PRR15 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1316889748; called by muse, mutect2, varscan2
- PTEN | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 217/344 reads (63%) | catalogued as CM110118, COSV64290316, COSV64291916, COSV64310910; called by muse, mutect2, varscan2
- QSER1 | c.907C>G p.P303A (on ENST00000399302; = p.P432A on NM_001076786.3) | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV101234947; called by muse, mutect2, varscan2
- RABL3 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 63/555 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56336671, COSV56337065; called by muse, mutect2, varscan2
- RACGAP1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs147422831; called by muse, mutect2, varscan2
- RANBP6 | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs888464596; called by muse, mutect2, varscan2
- RBM27 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs375122590; called by muse, mutect2, varscan2
- REV3L | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.517); catalogued as rs753723553; called by muse, mutect2, varscan2
- RIBC2 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV61581921; called by muse, mutect2, varscan2
- RIC8B | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as COSV62696730; called by muse, mutect2, varscan2
- RLF | c.1873C>G p.Q625E | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.098); catalogued as COSV65653141; called by muse, mutect2, varscan2
- RNF152 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777722574, COSV57183714; called by muse, mutect2, varscan2
- RNF17 | c.2471G>A p.C824Y | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99693830; called by muse, mutect2, varscan2
- SBNO1 | c.568A>T p.T190S (on ENST00000420886; = p.T189S on NM_018183.5) | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs775433568; called by muse, mutect2, varscan2
- SEMA4G | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 80/109 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866490784; called by muse, mutect2, varscan2
- SERPINB3 | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 89/281 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1459242450; called by muse, mutect2, varscan2
- SERTAD4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV104424008; called by muse, mutect2, varscan2
- SETD6 | c.938T>C p.I313T (on ENST00000219315 / NM_001160305.4; = p.I289T on NM_024860.3) | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751025928; called by muse, mutect2, varscan2
- SH3GL2 | c.629A>T p.E210V | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV101013926; called by muse, mutect2, varscan2
- SHANK1 | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs865912595; called by muse, mutect2, varscan2
- SI | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV52302137; called by muse, mutect2, varscan2
- SLAMF6 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 120/649 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63587895; called by muse, mutect2, varscan2
- SLC15A4 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 84/425 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as rs1322905778; called by muse, mutect2, varscan2
- SLC30A7 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as rs778750431, COSV100725530; called by muse, mutect2, varscan2
- SLITRK2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as COSV100157547; called by muse, varscan2
- SNTB1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs866095482; called by muse, mutect2, varscan2
- SNX18 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1300981657, COSV57990010; called by muse, mutect2, varscan2
- SP2 | c.1205C>G p.S402* | Nonsense Mutation (SNP) | VAF 60/622 reads (10%) | catalogued as COSV100947082; called by muse, mutect2, varscan2
- SPINT1 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1277192181, COSV100689240; called by muse, mutect2, varscan2
- SPRTN | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 51/347 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV50477903; called by muse, mutect2, varscan2
- SPTBN1 | c.6934G>T p.E2312* | Nonsense Mutation (SNP) | VAF 142/772 reads (18%) | catalogued as COSV63340562; called by muse, mutect2, varscan2
- SVEP1 | c.4022G>A p.R1341Q | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as rs753799251, COSV57028553; called by muse, mutect2, varscan2
- SYNE1 | c.3905G>A p.G1302E (on ENST00000367255 / NM_182961.4; = p.G1309E on NM_033071.3) | Missense Mutation (SNP) | VAF 433/816 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765195647; called by muse, mutect2, varscan2
- TCF20 | c.1396C>T p.L466F | Missense Mutation (SNP) | VAF 111/313 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59488197; called by muse, mutect2, varscan2
- TCF20 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100166415; called by muse, mutect2, varscan2
- TCTEX1D1 | c.337-2A>T p.X113_splice | Splice Site (SNP) | VAF 20/101 reads (20%) | catalogued as rs1446813094; called by muse, mutect2, varscan2
- TENM1 | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100948934; called by muse, mutect2, varscan2
- TENT4A | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1488932374; called by muse, mutect2, varscan2
- TLCD1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs368329414; called by muse, mutect2, varscan2
- TMEM200C | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs572639681; called by muse, mutect2, varscan2
- TNN | c.3784G>T p.G1262* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV53436224; called by muse, mutect2, varscan2
- TRIM51GP | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1217605446; called by muse, mutect2
- TRIM9 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53615429, COSV53620922; called by muse, mutect2, varscan2
- TRPC1 | c.1345G>C p.D449H (on ENST00000476941 / NM_001251845.2; = p.D415H on NM_003304.4) | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV56422734; called by muse, mutect2, varscan2
- TSC22D3 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 99/141 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs747569134; called by muse, mutect2, varscan2
- USP7 | c.2794G>C p.G932R | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as rs1476991127, COSV61216559; called by muse, varscan2
- USP8 | c.2675G>C p.R892T | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1487081071; called by muse, mutect2, varscan2
- WDCP | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs200535991; called by muse, mutect2, varscan2
- WNK2 | c.5875C>G p.L1959V (on ENST00000297954 / NM_001282394.1; = p.L1922V on NM_006648.3) | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1194256420; called by muse, mutect2, varscan2
- XIRP2 | c.118G>A p.E40K (on ENST00000628543; = p.E215K on NM_152381.6) | Missense Mutation (SNP) | VAF 88/405 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs1449740160, COSV54681396, COSV54689028; called by muse, mutect2, varscan2
- YES1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 143/787 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV58850802; called by muse, mutect2, varscan2
- ZEB2 | c.2761C>G p.R921G | Missense Mutation (SNP) | VAF 132/645 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as CM052018, COSV57966620; called by muse, mutect2, varscan2
- ZNF16 | c.1265A>G p.K422R | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.925); catalogued as COSV52763283; called by muse, mutect2
- ZNF160 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100762200; called by muse, mutect2, varscan2
- ZNF230 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV71273855; called by muse, mutect2, varscan2
- ZNF235 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs1434776259; called by muse, mutect2, varscan2
- ZNF334 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV61617988; called by muse, mutect2, varscan2
- ZNF521 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.405); catalogued as COSV64128964, COSV64129794; called by muse, mutect2, varscan2
- ZNF527 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.559); catalogued as COSV62229440; called by muse, mutect2, varscan2
- ZNF727 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 45/337 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs775703854, COSV101407130; called by muse, mutect2, varscan2
- ZNF800 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as COSV99758312; called by muse, mutect2, varscan2
- ZNF804A | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 169/369 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV56446676; called by muse, mutect2, varscan2
- A2M | c.4369G>C p.E1457Q | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCA2 | c.6286G>T p.G2096C (on ENST00000614293; = p.G2066C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB10 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 108/674 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ABCB4 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 86/589 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC5 | c.828C>T p.L276= | Splice Region (SNP) | VAF 32/233 reads (14%) | called by muse, mutect2, varscan2
- ABCF2 | c.1004T>A p.I335N | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ABHD10 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 100/708 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABL1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ACAD10 | c.936G>T p.R312S | Missense Mutation (SNP) | VAF 55/399 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACSL5 | c.1073T>A p.I358N (on ENST00000354273; = p.I414N on NM_016234.3) | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ACSM5 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ACVR2A | c.1149G>C p.L383F | Missense Mutation (SNP) | VAF 43/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADAM19 | c.2528C>T p.A843V | Missense Mutation (SNP) | VAF 84/125 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAM21 | c.1130dup p.N377Kfs*6 | Frame Shift Ins (INS) | VAF 132/225 reads (59%) | called by mutect2, varscan2
- ADSS2 | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.16589C>G p.S5530* | Nonsense Mutation (SNP) | VAF 63/185 reads (34%) | called by muse, mutect2, varscan2
- AHNAK2 | c.14632G>C p.A4878P | Missense Mutation (SNP) | VAF 179/263 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AKAP5 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ALYREF | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD1 | c.642T>A p.Y214* | Nonsense Mutation (SNP) | VAF 44/552 reads (8%) | called by muse, mutect2
- ANKAR | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ANKRD13B | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 119/187 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD13C | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD26 | c.3855G>C p.E1285D | Missense Mutation (SNP) | VAF 113/517 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ANKRD33B | c.1165C>G p.P389A | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD36 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 80/936 reads (9%) | called by muse, mutect2
- APOBEC1 | c.42G>A p.L14= | Splice Region (SNP) | VAF 73/544 reads (13%) | called by muse, mutect2, varscan2
- AREL1 | c.2278C>G p.Q760E | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARID4A | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 67/328 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARID4B | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 73/253 reads (29%) | called by muse, mutect2, varscan2
- ATAD2 | c.640A>T p.S214C | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ATAD2B | c.1193G>C p.R398P | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATN1 | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ATN1 | c.1094C>G p.S365C | Missense Mutation (SNP) | VAF 82/466 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.75); called by muse, varscan2
- ATP10D | c.502A>C p.I168L | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATP2A2 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 155/875 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2A2 | c.1715G>C p.R572T | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP5PD | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATRNL1 | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AWAT1 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- B4GALT4 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- BABAM2 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BCAS1 | c.1709T>G p.V570G | Missense Mutation (SNP) | VAF 21/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCL11B | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.585); called by muse, varscan2
- BCOR | c.4114G>C p.E1372Q (on ENST00000378444 / NM_001123385.2; = p.E1338Q on NM_017745.6) | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, varscan2
- BIRC6 | c.8948T>C p.L2983S | Missense Mutation (SNP) | VAF 130/353 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BMP4 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- BMPER | c.1600T>C p.C534R | Missense Mutation (SNP) | VAF 32/489 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRD1 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BRD9 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 76/518 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRINP1 | c.1463T>A p.L488Q | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BRINP3 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- BTBD2 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 147/232 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C1QTNF7 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C20orf204 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C3 | c.2583+3G>T | Splice Region (SNP) | VAF 306/481 reads (64%) | called by muse, mutect2, varscan2
- C4orf50 | c.397G>A p.G133R (on ENST00000324058; = p.G1365R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2
- CA5A | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CACNA1I | c.6184G>T p.A2062S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN13 | c.1875G>T p.R625S | Missense Mutation (SNP) | VAF 176/416 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CAPZA3 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 48/220 reads (22%) | called by muse, mutect2, varscan2
- CCDC141 | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CCDC168 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC57 | c.1080A>C p.K360N | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- CD1C | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 87/704 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CDH16 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 72/235 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CDK17 | c.1258G>C p.E420Q | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CDK9 | c.740C>G p.S247C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CEP83 | c.1638C>G p.I546M | Missense Mutation (SNP) | VAF 65/449 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CES1 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 163/840 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CGRRF1 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2
- CHAF1A | c.2327C>G p.P776R | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHKA | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CILP2 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 88/176 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CLK1 | c.101C>G p.S34* | Nonsense Mutation (SNP) | VAF 80/384 reads (21%) | called by muse, mutect2, varscan2
- CLSPN | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CMYA5 | c.8608A>G p.K2870E | Missense Mutation (SNP) | VAF 128/208 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CNPPD1 | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 164/373 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNR1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- COL14A1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL20A1 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 179/322 reads (56%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- COL6A3 | c.2441A>T p.Q814L | Missense Mutation (SNP) | VAF 138/261 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- COL8A1 | c.733T>A p.F245I | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COPB1 | c.2325G>C p.L775F | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- COX7B2 | c.71G>T p.R24I | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACDL | c.1825_1852del p.S609Vfs*86 | Frame Shift Del (DEL) | VAF 32/264 reads (12%) | called by mutect2, pindel
- CROCC2 | c.3215G>C p.R1072P | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CSMD3 | c.8837G>C p.S2946T (on ENST00000297405 / NM_001363185.1; = p.S2777T on NM_052900.3) | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CUBN | c.6030C>G p.I2010M | Missense Mutation (SNP) | VAF 187/314 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP3A5 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CYP4F8 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- DCC | c.4120C>A p.L1374I | Missense Mutation (SNP) | VAF 140/501 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DDHD2 | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- DDX60L | c.1279A>T p.K427* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | called by muse, mutect2
- DEPDC1 | c.1536T>A p.S512R | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DGKG | c.1209G>T p.R403= | Splice Region (SNP) | VAF 167/364 reads (46%) | called by muse, mutect2, varscan2
- DHCR24 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- DHPS | c.420C>G p.I140M | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DNAH10 | c.6173C>T p.S2058F (on ENST00000409039; = p.S1997F on NM_207437.3) | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH17 | c.1260C>A p.F420L | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- DNAI4 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DOCK10 | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- DPYSL5 | c.803T>C p.L268P | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- DSCAM | c.4816dup p.V1606Gfs*31 | Frame Shift Ins (INS) | VAF 160/325 reads (49%) | called by mutect2, pindel, varscan2
- DVL1 | c.1856G>T p.R619L (on ENST00000378888 / NM_001330311.2; = p.R594L on NM_004421.3) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- DYNC1I2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- E2F4 | c.1082-1G>C p.X361_splice | Splice Site (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- EAF2 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- EARS2 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF3 | c.791G>T p.C264F (on ENST00000355311 / NM_001375392.1; = p.C255F on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- ELMOD3 | c.528G>C p.Q176H | Missense Mutation (SNP) | VAF 76/395 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- EOGT | c.34C>G p.H12D | Missense Mutation (SNP) | VAF 117/361 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPS15L1 | c.930G>C p.Q310H | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- ERBIN | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 56/202 reads (28%) | called by muse, mutect2, varscan2
- ERICH6 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- EVX1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYA2 | c.1037G>A p.S346N | Missense Mutation (SNP) | VAF 94/416 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, varscan2
- EZH1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FAM171B | c.2181C>G p.I727M | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM185A | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- FAM187A | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 154/186 reads (83%) | called by muse, mutect2, varscan2
- FAM76A | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 69/369 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- FANCI | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 109/548 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FANCM | c.688A>T p.R230* | Nonsense Mutation (SNP) | VAF 224/307 reads (73%) | called by muse, mutect2, varscan2
- FARSB | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- FBN1 | c.6742G>A p.E2248K | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- FBXL14 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- FBXO28 | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 191/504 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- FBXO44 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 35/156 reads (22%) | called by muse, mutect2, varscan2
- FCRL5 | c.2238A>T p.A746= | Splice Region (SNP) | VAF 34/123 reads (28%) | called by muse, mutect2
- FER1L6 | c.3541G>C p.D1181H | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FER1L6 | c.4392-1G>C p.X1464_splice | Splice Site (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- FLRT2 | c.1703A>T p.K568I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- FNTB | c.1080C>G p.F360L | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FOXI2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXP2 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 67/499 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FSIP2 | c.12941C>A p.A4314D | Missense Mutation (SNP) | VAF 58/315 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FTO | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 148/466 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FZD8 | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GALK2 | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GBP4 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 86/180 reads (48%) | called by muse, mutect2, varscan2
- GC | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCNT2 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GLE1 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 152/601 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GLE1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 111/393 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLIS1 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- GNB2 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.207); called by muse, mutect2
- GOLGA6L2 | c.2104T>A p.C702S | Missense Mutation (SNP) | VAF 143/716 reads (20%) | SIFT tolerated, low confidence (0.85); called by muse, varscan2
- GPR101 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR153 | c.1658C>G p.S553C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK5 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRK7 | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM8 | c.261C>G p.N87K | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GTSF1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- H2BC8 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HADHB | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 78/501 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- HEATR5B | c.3184G>A p.V1062I | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HECTD4 | c.3853G>C p.D1285H | Missense Mutation (SNP) | VAF 136/704 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- HECTD4 | c.2385A>T p.L795F | Missense Mutation (SNP) | VAF 128/423 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- HECW1 | c.2503_2521delinsCC p.W835Pfs*80 | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by pindel, varscan2*
- HELB | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 84/545 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.6607G>A p.G2203S (on ENST00000467148 / NM_001037335.2; = p.G1634S on NM_033405.3) | Missense Mutation (SNP) | VAF 60/102 reads (59%) | SIFT tolerated (0.8); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HFM1 | c.2688_2735del p.D897_S912del | In Frame Del (DEL) | VAF 38/122 reads (31%) | called by mutect2, pindel
- HIVEP3 | c.4298C>T p.S1433L | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HMCN2 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HNRNPH3 | c.624A>C p.E208D | Missense Mutation (SNP) | VAF 176/455 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- IFIH1 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFT81 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- INSC | c.1704C>G p.F568L | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ITGA10 | c.2755G>C p.E919Q | Missense Mutation (SNP) | VAF 91/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JMJD1C | c.3192C>G p.I1064M | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KCNA7 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KCNH5 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK18 | c.417T>A p.F139L | Missense Mutation (SNP) | VAF 267/586 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- KCTD12 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- KIAA0825 | c.3054G>C p.L1018F | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF1A | c.4814T>C p.V1605A (on ENST00000320389 / NM_001379639.1; = p.V1597A on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KIF2A | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 106/193 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIF2A | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- KIR2DL3 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 262/575 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL31 | c.1105G>C p.V369L | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- KMT5C | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KNTC1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- KRIT1 | c.976C>G p.H326D | Missense Mutation (SNP) | VAF 137/491 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- KRT18 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- LACRT | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 53/441 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LEFTY2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 122/587 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- LENG8 | c.1600A>C p.S534R | Missense Mutation (SNP) | VAF 101/532 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LEPR | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 274/615 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LEPROTL1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 74/548 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LPP | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 78/374 reads (21%) | called by muse, mutect2, varscan2
- LRRC7 | c.1389C>A p.Y463* (on ENST00000651989 / NM_001370785.2; = p.Y430* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | called by muse, mutect2, varscan2
- LRRTM1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 76/375 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 71/323 reads (22%) | called by muse, mutect2, varscan2
- MAP3K14 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP3K19 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2
- MAP3K9 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- MBTD1 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 184/244 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MC5R | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCM9 | c.2887G>T p.D963Y | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- MCUR1 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MDFIC | c.-107-1G>C | Splice Site (SNP) | VAF 37/371 reads (10%) | called by muse, mutect2, varscan2
- MICAL3 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 39/209 reads (19%) | called by muse, mutect2, varscan2
- MIOS | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 53/467 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MKRN3 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 90/305 reads (30%) | called by muse, mutect2, varscan2
- MRC1 | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 186/737 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- MRPS14 | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSMB | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2
- MTCH2 | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MTMR6 | c.640T>G p.C214G | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MUC19 | c.162+6G>C | Splice Region (SNP) | VAF 78/248 reads (31%) | called by muse, mutect2, varscan2
- MYO1G | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAALADL2 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | called by muse, mutect2, varscan2
- NBEAL2 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 130/202 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NBEAL2 | c.6122G>T p.R2041L | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCK2 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NEK11 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NFXL1 | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NGEF | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- NIM1K | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRP2 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRP2 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 205/413 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSMCE4A | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NUP210L | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUP54 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- OBSCN | c.13709_13711del p.R4570del | In Frame Del (DEL) | VAF 56/323 reads (17%) | called by pindel, varscan2
- OR13C2 | c.885C>G p.I295M | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR14I1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2L13 | c.419G>C p.C140S | Missense Mutation (SNP) | VAF 99/664 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4C13 | c.440G>T p.W147L | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- OR4Q2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- OR5M10 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 100/175 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR5T1 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 140/256 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8S1 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 120/384 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD7A | c.1112A>G p.D371G (on ENST00000307050 / NM_001382637.1; = p.D364G on NM_130901.3) | Missense Mutation (SNP) | VAF 81/290 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAPSS1 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 119/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.2543C>G p.A848G | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PCDHB7 | c.2128C>G p.R710G | Missense Mutation (SNP) | VAF 202/958 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PCDHGA10 | c.1236A>T p.R412S | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCF11 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- PFN2 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PGK1 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- PGR | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 256/373 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PGS1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PIWIL1 | c.1274T>C p.I425T | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PKN3 | c.1268G>T p.R423L | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLAAT1 | c.464C>T p.P155L (on ENST00000650797; = p.P50L on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, varscan2
- PLD5 | c.833G>C p.R278T (on ENST00000442594; = p.R216T on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/517 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PLEKHA7 | c.3034C>G p.Q1012E | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLEKHG1 | c.3588C>G p.I1196M | Missense Mutation (SNP) | VAF 141/761 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PLS1 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLS3 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- PMPCB | c.37del p.A13Rfs*14 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- POLR1G | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 74/258 reads (29%) | called by muse, mutect2, varscan2
- POTEH | c.71dup p.M24Ifs*165 | Frame Shift Ins (INS) | VAF 200/1028 reads (19%) | called by pindel, varscan2
- PPL | c.3639G>C p.Q1213H | Missense Mutation (SNP) | VAF 90/371 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- PPP6R2 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF4 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 178/791 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- PRPF8 | c.789C>G p.F263L | Missense Mutation (SNP) | VAF 154/467 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRR14L | c.5109G>C p.L1703F | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PRR14L | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PRR14L | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PTPRQ | c.5644G>C p.E1882Q (on ENST00000616559; = p.E1840Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 123/630 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- RAI14 | c.36C>G p.D12E | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- RALGAPA1 | c.3446A>G p.Y1149C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); called by mutect2, varscan2
- RASGRP4 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 88/371 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RASIP1 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RASIP1 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- RBM15B | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM47 | c.395_409del p.N132_R137delinsS | In Frame Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- RDH11 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REST | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 95/403 reads (24%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RHEBL1 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 46/244 reads (19%) | called by muse, mutect2, varscan2
- RHOF | c.591G>C p.K197N | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RIBC2 | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- RIMS1 | c.4119G>T p.R1373S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, varscan2
- RNASEH2C | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 154/514 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- RNASEH2C | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- RNF13 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPH3A | c.428G>A p.C143Y (on ENST00000389385 / NM_001143854.2; = p.C139Y on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/433 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPS6KA2 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RSPO1 | c.725G>C p.R242P | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, varscan2
- RTTN | c.2000A>T p.H667L | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RUSF1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RYR1 | c.3302dup p.W1103Lfs*9 | Frame Shift Ins (INS) | VAF 209/577 reads (36%) | called by mutect2, pindel, varscan2
- SCN4A | c.1553G>C p.G518A | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCN5A | c.4237C>G p.L1413V (on ENST00000333535 / NM_198056.3; = p.L1412V on NM_000335.5) | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA4D | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SHC4 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHISA6 | c.929A>G p.K310R (on ENST00000409168 / NM_001173461.1; = p.K361R on NM_207386.4) | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHQ1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC12A2 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A2 | c.2416C>T p.H806Y | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC13A4 | c.1734C>G p.I578M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC16A9 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 84/388 reads (22%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLCO1B1 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLCO1B3 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMAP1 | c.838G>T p.G280W (on ENST00000370455 / NM_001044305.3; = p.G253W on NM_021940.5) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SOCS6 | c.222G>T p.M74I | Missense Mutation (SNP) | VAF 115/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SORBS1 | c.2957C>G p.S986C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOS2 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 74/310 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- SP100 | c.1499G>T p.R500I | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SPAG17 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- SPTAN1 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 162/579 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.27); called by muse, varscan2
- SREBF2 | c.1535A>T p.H512L | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRT | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 77/442 reads (17%) | called by muse, mutect2, varscan2
- SS18L1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.666A>T p.K222N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- STAG3 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); called by muse, varscan2
- STAT1 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- STK31 | c.1766T>C p.L589P | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- STK31 | c.2089C>T p.Q697* | Nonsense Mutation (SNP) | VAF 154/373 reads (41%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2818C>T p.Q940* | Nonsense Mutation (SNP) | VAF 76/486 reads (16%) | called by muse, mutect2, varscan2
- STRIP1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STX12 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYMPK | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SYNPO | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 136/231 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TAGAP | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TAS1R2 | c.1638G>C p.Q546H | Missense Mutation (SNP) | VAF 117/507 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TBC1D9B | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TCF20 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 140/508 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TECPR1 | c.2209A>C p.K737Q | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TFCP2L1 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 97/198 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- THEM4 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 89/413 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- TJP1 | c.1243G>C p.D415H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- TMEM132D | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM178A | c.127T>A p.C43S | Missense Mutation (SNP) | VAF 179/553 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMEM178B | c.408C>G p.I136M | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TMEM61 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 115/215 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM63A | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TNFAIP2 | c.1374G>C p.K458N | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TNFAIP2 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TNRC18 | c.6163G>A p.E2055K | Missense Mutation (SNP) | VAF 73/518 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TPMT | c.717A>T p.L239F | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TRAK2 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TRAPPC10 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TRAPPC10 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by mutect2, varscan2
- TRAV24 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- TRDN | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRIL | c.2150G>C p.W717S | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TRIM28 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- TRIM45 | c.1016C>A p.S339* | Nonsense Mutation (SNP) | VAF 131/742 reads (18%) | called by muse, mutect2, varscan2
- TRIM46 | c.2279G>C p.*760Sext*85 | Nonstop Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- TROAP | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRPA1 | c.3285G>C p.Q1095H | Missense Mutation (SNP) | VAF 164/912 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPS1 | c.755A>G p.N252S (on ENST00000220888 / NM_001330599.2; = p.N265S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TTC27 | c.202A>G p.S68G | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.127); called by muse, mutect2
- TTC6 | c.1716G>T p.M572I | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.36023C>A p.P12008H (on ENST00000591111; = p.P4584H on NM_003319.4) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | PolyPhen probably damaging (0.999); called by muse, varscan2
- TUBA1A | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 118/838 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UBC | c.1668G>T p.E556D | Missense Mutation (SNP) | VAF 80/845 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, varscan2
- UBC | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 177/1120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, varscan2
- UBR1 | c.2708C>G p.S903C | Missense Mutation (SNP) | VAF 138/508 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, varscan2
- UCHL5 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC45B | c.2501C>A p.A834E | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UNC5D | c.942G>T p.W314C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNKL | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 83/191 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UPP1 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- USP17L2 | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 40/316 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- USP40 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 74/273 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP15 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTRN | c.2756T>G p.L919R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- UVRAG | c.769G>C p.A257P | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- VSIG10L | c.2305+1G>A p.X769_splice | Splice Site (SNP) | VAF 28/56 reads (50%) | called by mutect2, varscan2
- VWA5B2 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR3 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 42/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- WDR33 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR7 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- WDR97 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WFS1 | c.2275C>A p.L759M | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ZBED9 | c.2659G>C p.D887H | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC4H2 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMIZ2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZMPSTE24 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF160 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF214 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF276 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ZNF284 | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF286A | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF438 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 95/505 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF536 | c.2881G>C p.G961R | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF566 | c.456G>C p.L152F | Missense Mutation (SNP) | VAF 98/441 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF670 | c.998G>C p.G333A | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- ZNF695 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ZNF716 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF729 | c.512A>T p.K171M | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.3734G>T p.C1245F | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ZNF790 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF816 | c.1830A>C p.K610N | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF83 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ZNF846 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ZNF853 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 17/412 reads (4%) | called by muse, mutect2
- ZNF880 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF90 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 90/336 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.7); called by muse, varscan2
- ZP2 | c.1591C>G p.L531V | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZSWIM4 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ZZEF1 | c.8359G>C p.E2787Q | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ABCA1 | c.213G>A p.Q71= | Silent (SNP) | VAF 166/667 reads (25%) | called by muse, mutect2, varscan2
- ABCG1 | c.1071C>T p.L357= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1662C>G p.L554= (on ENST00000341937 / NM_001130084.2; = p.L464= on NM_032432.5) | Silent (SNP) | VAF 93/399 reads (23%) | called by muse, mutect2, varscan2
- ACSS3 | c.537A>T p.P179= | Silent (SNP) | VAF 40/281 reads (14%) | called by muse, mutect2, varscan2
- ACVR1C | c.66C>G p.L22= | Silent (SNP) | VAF 68/362 reads (19%) | called by muse, mutect2
- ADAMTSL4 | c.234C>G p.L78= | Silent (SNP) | VAF 20/235 reads (9%) | called by muse, mutect2
- ADCY6 | c.519C>T p.P173= | Silent (SNP) | VAF 18/278 reads (6%) | catalogued as rs561521194; called by muse, mutect2
- ADGRL3 | c.1206T>G p.A402= (on ENST00000506720 / NM_001322402.2; = p.A334= on NM_015236.6) | Silent (SNP) | VAF 153/206 reads (74%) | called by muse, mutect2, varscan2
- AFMID | c.726C>G p.V242= | Silent (SNP) | VAF 45/298 reads (15%) | catalogued as COSV100014910; called by muse, mutect2, varscan2
- AHNAK | c.16174C>T p.L5392= | Silent (SNP) | VAF 48/206 reads (23%) | called by muse, mutect2, varscan2
- AJM1 | c.513C>T p.C171= | Silent (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- AKAP11 | c.4998G>C p.L1666= | Silent (SNP) | VAF 51/173 reads (29%) | called by muse, mutect2, varscan2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as rs766848323, COSV59273976; called by muse, mutect2, varscan2
- ALAS2 | c.903C>A p.V301= | Silent (SNP) | VAF 179/224 reads (80%) | called by muse, mutect2, varscan2
- ALCAM | c.738A>G p.T246= | Silent (SNP) | VAF 120/272 reads (44%) | called by muse, mutect2, varscan2
- ANAPC1 | c.3210G>A p.L1070= | Silent (SNP) | VAF 131/381 reads (34%) | catalogued as rs2685953; called by muse, mutect2, varscan2
- ANKRD26 | c.2487G>A p.V829= | Silent (SNP) | VAF 64/267 reads (24%) | called by muse, mutect2, varscan2
- AP1M2 | c.807C>T p.L269= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- AP4B1 | c.378C>G p.L126= | Silent (SNP) | VAF 335/831 reads (40%) | called by muse, mutect2, varscan2
- APCDD1 | c.765G>A p.Q255= | Silent (SNP) | VAF 127/626 reads (20%) | called by muse, mutect2, varscan2
- APP | c.2169G>A p.L723= | Silent (SNP) | VAF 134/476 reads (28%) | catalogued as COSV61005280; called by muse, mutect2, varscan2
- BRWD3 | c.2178C>T p.L726= | Silent (SNP) | VAF 43/128 reads (34%) | called by muse, mutect2, varscan2
- BTG2 | c.372G>A p.E124= | Silent (SNP) | VAF 95/239 reads (40%) | called by muse, mutect2, varscan2
- C1orf226 | c.186G>A p.V62= | Silent (SNP) | VAF 145/708 reads (20%) | called by muse, mutect2, varscan2
- CAD | c.4641C>T p.T1547= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as rs773275010, COSV99254985; called by muse, mutect2, varscan2
- CAMK1 | c.273C>G p.L91= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as COSV56540007; called by muse, mutect2, varscan2
- CATSPER3 | c.858G>A p.Q286= | Silent (SNP) | VAF 343/515 reads (67%) | called by muse, mutect2, varscan2
- CCDC40 | c.2523G>A p.K841= | Silent (SNP) | VAF 138/650 reads (21%) | called by muse, mutect2, varscan2
- CD163 | c.153G>C p.L51= | Silent (SNP) | VAF 64/283 reads (23%) | catalogued as rs764416279, COSV100776105; called by muse, mutect2, varscan2
- CD55 | c.9C>T p.V3= | Silent (SNP) | VAF 53/224 reads (24%) | catalogued as rs759295269; called by muse, mutect2, varscan2
- CDC25C | c.915C>G p.V305= | Silent (SNP) | VAF 66/299 reads (22%) | called by muse, mutect2, varscan2
- CFAP74 | c.471G>A p.S157= | Silent (SNP) | VAF 101/221 reads (46%) | catalogued as rs370515060, COSV54565705, COSV99574921; called by muse, mutect2, varscan2
- CGB8 | c.336C>G p.L112= | Silent (SNP) | VAF 4/8 reads (50%) | called by mutect2, varscan2
- CHD5 | c.4821G>A p.K1607= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as rs888174519; called by muse, mutect2, varscan2
- CHST6 | c.675G>A p.V225= | Silent (SNP) | VAF 88/291 reads (30%) | called by muse, mutect2, varscan2
- CLCA2 | c.2649G>A p.Q883= | Silent (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- CPED1 | c.2919A>G p.R973= | Silent (SNP) | VAF 62/372 reads (17%) | called by muse, mutect2, varscan2
- CPZ | c.1461C>G p.L487= (on ENST00000360986 / NM_001014447.3; = p.L476= on NM_003652.3) | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV59925394; called by muse, mutect2
- CRACR2A | c.1662C>T p.S554= | Silent (SNP) | VAF 102/646 reads (16%) | catalogued as rs756655299, COSV100411341; called by muse, mutect2, varscan2
- CRPPA | c.783C>G p.L261= (on ENST00000407010 / NM_001368197.1; = p.L211= on NM_001101417.4) | Silent (SNP) | VAF 103/322 reads (32%) | catalogued as COSV101235362; called by muse, mutect2, varscan2
- CTNNA2 | c.1785C>A p.A595= | Silent (SNP) | VAF 51/267 reads (19%) | catalogued as COSV100562203, COSV58157772; called by muse, mutect2
- CTSZ | c.75C>G p.L25= | Silent (SNP) | VAF 40/407 reads (10%) | catalogued as rs951527175; called by muse, mutect2
- CYP4V2 | c.475C>T p.L159= | Silent (SNP) | VAF 83/283 reads (29%) | called by muse, mutect2, varscan2
- DENND2A | c.2259C>A p.R753= | Silent (SNP) | VAF 133/475 reads (28%) | called by muse, mutect2, varscan2
- DNAH11 | c.6525T>C p.N2175= | Silent (SNP) | VAF 200/468 reads (43%) | called by muse, mutect2, varscan2
- DNAH3 | c.4272G>T p.G1424= | Silent (SNP) | VAF 110/264 reads (42%) | called by muse, mutect2, varscan2
- DNTTIP1 | c.294G>A p.L98= | Silent (SNP) | VAF 45/268 reads (17%) | catalogued as COSV54784179, COSV54784704; called by muse, mutect2, varscan2
- DOCK4 | c.3351G>A p.L1117= | Silent (SNP) | VAF 121/690 reads (18%) | catalogued as rs548719991; called by muse, mutect2, varscan2
- EGR4 | c.138G>A p.A46= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as rs1157490178; called by muse, mutect2, varscan2
- EIF6 | c.666C>T p.F222= | Silent (SNP) | VAF 106/543 reads (20%) | catalogued as rs749948879; called by muse, mutect2, varscan2
- EPHA10 | c.372G>A p.E124= | Silent (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- EVX2 | c.276C>T p.I92= | Silent (SNP) | VAF 170/771 reads (22%) | catalogued as rs764564856; called by muse, mutect2, varscan2
- FAM151A | c.6C>G p.V2= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as COSV100156989; called by muse, mutect2, varscan2
- FAT1 | c.5190G>A p.L1730= | Silent (SNP) | VAF 33/109 reads (30%) | called by muse, mutect2, varscan2
- FNDC1 | c.2421G>A p.T807= | Silent (SNP) | VAF 56/240 reads (23%) | catalogued as rs1028491793, COSV51940488, COSV51944638; called by muse, mutect2, varscan2
- FRY | c.2706C>T p.T902= | Silent (SNP) | VAF 50/273 reads (18%) | called by muse, mutect2, varscan2
- GEMIN6 | c.246G>C p.L82= | Silent (SNP) | VAF 143/447 reads (32%) | catalogued as COSV99931568; called by muse, mutect2, varscan2
- GIGYF2 | c.3843C>G p.V1281= | Silent (SNP) | VAF 116/647 reads (18%) | catalogued as rs536044025, COSV101004676; called by muse, mutect2, varscan2
- GPN1 | c.552C>T p.F184= | Silent (SNP) | VAF 29/263 reads (11%) | called by muse, mutect2, varscan2
- GRHL2 | c.141C>T p.A47= | Silent (SNP) | VAF 95/310 reads (31%) | called by muse, varscan2
- GSDMA | c.120G>A p.L40= | Silent (SNP) | VAF 108/475 reads (23%) | called by muse, mutect2, varscan2
- H6PD | c.162G>T p.A54= | Silent (SNP) | VAF 196/788 reads (25%) | catalogued as COSV66232043; called by muse, mutect2, varscan2
- HELB | c.330G>T p.P110= | Silent (SNP) | VAF 162/491 reads (33%) | catalogued as rs531762590, COSV56073859; called by muse, mutect2, varscan2
- HIRA | c.2515C>T p.L839= | Silent (SNP) | VAF 78/315 reads (25%) | called by muse, mutect2, varscan2
- HR | c.378T>C p.H126= | Silent (SNP) | VAF 212/469 reads (45%) | called by muse, mutect2, varscan2
- ICA1 | c.1275C>T p.F425= | Silent (SNP) | VAF 229/556 reads (41%) | catalogued as rs972454002, COSV55585270; called by muse, mutect2, varscan2
- IGKV5-2 | c.24C>G p.L8= | Silent (SNP) | VAF 112/838 reads (13%) | called by muse, mutect2, varscan2
- IGLV4-3 | c.312C>T p.D104= | Silent (SNP) | VAF 52/556 reads (9%) | catalogued as rs371756657; called by muse, mutect2
- ISM2 | c.291C>T p.P97= | Silent (SNP) | VAF 121/186 reads (65%) | called by muse, mutect2, varscan2
- ITCH | c.862C>T p.L288= (on ENST00000262650 / NM_001257137.3; = p.L247= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as COSV52929497, COSV52930314; called by muse, mutect2, varscan2
- IVL | c.946C>T p.L316= | Silent (SNP) | VAF 239/459 reads (52%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.831C>T p.V277= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as rs1560161964; called by muse, mutect2, varscan2
- JUNB | c.879C>T p.I293= | Silent (SNP) | VAF 102/311 reads (33%) | catalogued as rs889966481, COSV56878245, COSV56878450; called by muse, varscan2
- KANK3 | c.1656G>C p.L552= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- KATNBL1 | c.678A>T p.L226= | Silent (SNP) | VAF 44/149 reads (30%) | called by muse, mutect2, varscan2
- KCNK18 | c.981G>T p.G327= | Silent (SNP) | VAF 399/1104 reads (36%) | catalogued as COSV57971224; called by mutect2, varscan2
- KIR2DL3 | c.456G>A p.R152= | Silent (SNP) | VAF 71/352 reads (20%) | catalogued as COSV100667844; called by muse, mutect2, varscan2
- KLK6 | c.711C>T p.I237= | Silent (SNP) | VAF 62/255 reads (24%) | catalogued as COSV100037712; called by muse, mutect2, varscan2
- KRI1 | c.558G>A p.Q186= | Silent (SNP) | VAF 72/256 reads (28%) | called by muse, mutect2, varscan2
- LCAT | c.12C>A p.P4= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as COSV50454645; called by muse, mutect2, varscan2
- LCORL | c.1401T>G p.S467= | Silent (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- LRRC24 | c.333C>A p.R111= | Silent (SNP) | VAF 85/360 reads (24%) | called by muse, mutect2, varscan2
- MAP4K1 | c.1656C>G p.L552= | Silent (SNP) | VAF 58/252 reads (23%) | catalogued as COSV101204197; called by muse, varscan2
- MC1R | c.693C>A p.V231= | Silent (SNP) | VAF 102/302 reads (34%) | called by mutect2, varscan2
- MCMDC2 | c.1492T>C p.L498= | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as rs774032903; called by muse, mutect2, varscan2
- MORC1 | c.2586G>A p.L862= | Silent (SNP) | VAF 60/462 reads (13%) | called by muse, mutect2, varscan2
- MRPL32 | c.87G>A p.R29= | Silent (SNP) | VAF 19/203 reads (9%) | catalogued as rs1367806124; called by muse, mutect2
- MRPS22 | c.468G>T p.V156= (on ENST00000310776 / NM_001363893.1; = p.V157= on NM_020191.4) | Silent (SNP) | VAF 149/421 reads (35%) | called by muse, mutect2, varscan2
- MSR1 | c.201C>T p.L67= | Silent (SNP) | VAF 109/541 reads (20%) | catalogued as rs908475649; called by muse, mutect2, varscan2
- MUC5AC | c.13707C>A p.P4569= | Silent (SNP) | VAF 325/539 reads (60%) | catalogued as rs796727469; called by muse, mutect2, varscan2
- MYO10 | c.3852C>T p.A1284= | Silent (SNP) | VAF 130/414 reads (31%) | catalogued as rs747489658; called by muse, mutect2, varscan2
- MYO10 | c.900C>T p.I300= | Silent (SNP) | VAF 36/229 reads (16%) | catalogued as rs187325024; called by muse, mutect2, varscan2
- MYO6 | c.510A>G p.E170= | Silent (SNP) | VAF 95/343 reads (28%) | called by muse, mutect2, varscan2
- NAGPA | c.885C>G p.L295= | Silent (SNP) | VAF 138/613 reads (23%) | catalogued as COSV56569376; called by muse, mutect2, varscan2
- NAMPT | c.1446G>A p.L482= | Silent (SNP) | VAF 58/338 reads (17%) | called by muse, mutect2, varscan2
- NAV3 | c.3396C>A p.T1132= | Silent (SNP) | VAF 68/343 reads (20%) | catalogued as rs1233057303, COSV99889469; called by muse, mutect2, varscan2
- NCAPG | c.1125C>T p.I375= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- NDUFB5 | c.81C>G p.L27= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV99372519; called by muse, mutect2, varscan2
- NEB | c.5823C>A p.G1941= | Silent (SNP) | VAF 152/291 reads (52%) | catalogued as COSV51466239; called by muse, mutect2, varscan2
- NECTIN4 | c.870C>T p.P290= | Silent (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- NLRP11 | c.1524G>A p.E508= | Silent (SNP) | VAF 47/272 reads (17%) | called by muse, mutect2, varscan2
- NPAP1 | c.1011G>T p.P337= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV61505934; called by muse, mutect2, varscan2
- NSUN2 | c.1680C>G p.L560= | Silent (SNP) | VAF 69/420 reads (16%) | called by muse, mutect2, varscan2
- NT5C3B | c.732G>A p.V244= | Silent (SNP) | VAF 246/346 reads (71%) | called by muse, mutect2, varscan2
- NTNG1 | c.786G>A p.L262= | Silent (SNP) | VAF 57/287 reads (20%) | called by muse, mutect2, varscan2
- NUTM2G | c.2046G>A p.K682= | Silent (SNP) | VAF 74/136 reads (54%) | called by mutect2, varscan2
- NVL | c.2334A>T p.A778= | Silent (SNP) | VAF 100/314 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.13704G>A p.Q4568= | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as rs1211689043, COSV99471771; called by mutect2, varscan2
- OGFOD2 | c.435C>T p.F145= (on ENST00000228922 / NM_001304833.1; = p.F85= on NM_024623.3) | Silent (SNP) | VAF 52/307 reads (17%) | catalogued as COSV99965593; called by muse, mutect2, varscan2
- OR10J3 | c.585C>T p.V195= | Silent (SNP) | VAF 138/759 reads (18%) | called by muse, mutect2, varscan2
- OR2L2 | c.663C>G p.L221= | Silent (SNP) | VAF 69/481 reads (14%) | catalogued as rs983080021, COSV63547447; called by muse, mutect2
- OR4K15 | c.564T>A p.V188= (on ENST00000305051; = p.V164= on NM_001005486.1) | Silent (SNP) | VAF 23/237 reads (10%) | called by muse, mutect2
- OR4K5 | c.501T>A p.P167= | Silent (SNP) | VAF 74/507 reads (15%) | called by muse, mutect2, varscan2
- OR52N5 | c.759T>C p.H253= | Silent (SNP) | VAF 88/129 reads (68%) | called by muse, mutect2, varscan2
- PCDH17 | c.369G>A p.Q123= | Silent (SNP) | VAF 172/337 reads (51%) | catalogued as rs1247299555; called by muse, mutect2, varscan2
- PCSK5 | c.5109C>G p.L1703= | Silent (SNP) | VAF 76/269 reads (28%) | called by muse, mutect2, varscan2
- PHF19 | c.1011C>T p.F337= | Silent (SNP) | VAF 76/281 reads (27%) | called by muse, mutect2, varscan2
- PLXNC1 | c.4068G>A p.S1356= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as rs751360894; called by muse, mutect2, varscan2
- POU4F2 | c.843C>A p.S281= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs770276185, COSV55585014; called by muse, mutect2, varscan2
- PRAMEF8 | c.1104C>T p.I368= | Silent (SNP) | VAF 98/681 reads (14%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.363C>A p.V121= | Silent (SNP) | VAF 128/685 reads (19%) | called by muse, mutect2, varscan2
- RNF152 | c.210G>T p.P70= | Silent (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- ROR1 | c.18C>T p.R6= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- RPUSD1 | c.516G>A p.R172= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- RXFP1 | c.2205G>C p.P735= | Silent (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- RXYLT1 | c.15G>C p.R5= | Silent (SNP) | VAF 92/597 reads (15%) | called by muse, mutect2, varscan2
- RYR3 | c.858C>G p.L286= | Silent (SNP) | VAF 85/299 reads (28%) | catalogued as COSV66798738; called by muse, mutect2, varscan2
- SAFB2 | c.228C>A p.I76= | Silent (SNP) | VAF 79/272 reads (29%) | called by muse, mutect2, varscan2
- SALL3 | c.1446C>T p.Y482= | Silent (SNP) | VAF 51/105 reads (49%) | catalogued as rs1416446904; called by muse, mutect2, varscan2
- SAMD10 | c.15G>C p.L5= | Silent (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2
- SCN5A | c.5901C>T p.S1967= (on ENST00000333535 / NM_198056.3; = p.S1966= on NM_000335.5) | Silent (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- SERINC5 | c.63C>G p.L21= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs375192791, COSV101549047; called by muse, mutect2, varscan2
- SHANK3 | c.1431G>T p.P477= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs1364332468; called by muse, mutect2, varscan2
- SKOR1 | c.1872G>A p.P624= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- SLC27A2 | c.924C>A p.V308= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- SLC39A7 | c.273C>T p.G91= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as rs751268554; called by muse, mutect2, varscan2
- SLITRK2 | c.531G>A p.V177= | Silent (SNP) | VAF 33/78 reads (42%) | called by muse, varscan2
- SNAPC1 | c.750A>T p.S250= | Silent (SNP) | VAF 40/124 reads (32%) | called by muse, varscan2
- SSPN | c.87G>A p.P29= | Silent (SNP) | VAF 39/172 reads (23%) | catalogued as rs1338816115; called by muse, mutect2, varscan2
- STAT6 | c.1761G>A p.E587= | Silent (SNP) | VAF 73/363 reads (20%) | catalogued as rs1317053901; called by muse, mutect2, varscan2
- STK32B | c.777G>A p.L259= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1248556876; called by muse, mutect2, varscan2
- TANGO6 | c.2838A>T p.A946= | Silent (SNP) | VAF 65/183 reads (36%) | called by muse, mutect2, varscan2
- TAP1 | c.111G>A p.R37= | Silent (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- TEX15 | c.8082G>A p.L2694= (on ENST00000256246; = p.L3077= on NM_001350162.2) | Silent (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
142 further variants in this file (0 protein-altering or splice-affecting, 23 silent, 119 other) are not listed here.
